Somatic mutation profile of tumor specimen TCGA-50-5055-01A (aliquot TCGA-50-5055-01A-01D-1625-08) from TCGA case TCGA-50-5055, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.4 years (28,988 days).
Specimen TCGA-50-5055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 211adb3c-94b0-4103-87ef-26a3e2b047ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5055-10A (Blood Derived Normal), aliquot TCGA-50-5055-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c637fff5-ea5c-4339-948a-269ff75d1899

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYBB | c.1072G>C p.V358L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV101059723, COSV66085391, COSV66085499; called by muse, mutect2
- FKBP3 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53532449; called by muse, mutect2
- GRIK5 | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53488114; called by muse, mutect2, varscan2
- HIVEP1 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65101398; called by muse, mutect2
- KNTC1 | c.6526G>A p.A2176T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs776590958, COSV61080168; called by muse, mutect2, varscan2
- MCU | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs763876457, COSV64066184; called by muse, mutect2, varscan2
- TMEM117 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56904440; called by muse, mutect2
- TPR | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs990651752, COSV66601380; called by muse, mutect2
- XIRP2 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99736883; called by muse, mutect2
- XIRP2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99736892; called by muse, mutect2
